Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADY, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADY-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular carcinoma suggested (S6)

Specimen : Liver and Liver mass

Gross Photo :

GROSS:

Specimen status: Fresh

Operation:

Right hepatectomy (Right posterior sectionectomy and segmentectomy 5)

Cholecystectomy

Organs:

Liver (16.5 x 10.5 x 5.8 cm, 437.0 gm)

Gallbladder (7.3 cm in length, 2.8 cm in diameter, 0.5 cm in wall thickness)

Lesion: A well-defined mass (4.3 x 3.7 x 3.3 cm) in right lobe

Cut surface: Yellowish tan, and granular with area of hemorrhage

Gross type:

HCC: Expanding nodular

Resection margin: Not involved grossly (safety margin: 0.4 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Cirrhotic

Representative sections submitted

Gross photo: Present

Blocks

T1-6, TB, tumor mass x 7

L, liver parenchyma x 1

GB, gallbladder x 1

MICROSCOPIC:

Hepatocellular carcinoma: Yes

The worst differentiation II

The major differentiation II

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: Complete capsule

Capsular infiltration: No

Septum formation: No

Surgical resection margin invasion: No

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

Intrahepatic metastasis: Unknown

Multicentric occurrence: Unknown

ICD O-3

Carcinoma, hepatocellular NOS
8/70/3

Site: Liver C22.0
9/5/20/14

[page 2 of 2]
NOT reported. Gross:

Liver, right, ectomy, hepatocellular carcinoma, moderately differentiated

T56000, right, P10, M81703, moderately differentiated

Gallbladder, ectomy, chronic cholecystitis

T57000, P10, M43005

DIAGNOSIS:

Liver, right lobe, right hepatectomy:

Hepatocellular carcinoma, moderately differentiated

Cirrhosis, micronodular

Gallbladder, cholecystectomy: Chronic cholecystitis

Suggestion :

Source: NCI Genomic Data Commons file 17350ba5-8204-450f-927a-ef1370432735 (TCGA-DD-AADY.49B92F18-C6E7-4704-A6DD-F098A4B74DDA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).